TCGA case TCGA-N8-A56S — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Corpus uteri; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/33ad8d6e-10f4-4965-9721-1a9984f9e87d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead; Days to death: 371 days (1.0 years).

Diagnoses (3)
1. Mullerian mixed tumor (the primary disease): ICD-O-3 morphology code: 8950/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 75.3 years (27,519 days); Year of diagnosis: 2012; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IB; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 371 days (1.0 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 94.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 57 days; Days to treatment end: 183 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Mullerian mixed tumor), site: Lung, NOS. Age at diagnosis: 75.9 years (27,718 days); Days to diagnosis: 199 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
3. Progression of diagnosis 1 (Mullerian mixed tumor), site: Lymph node, NOS. Age at diagnosis: 75.9 years (27,718 days); Days to diagnosis: 199 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Days to follow up: 155 days; Disease response: With Tumor.
- Day 199 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 199 days.
- Day 199 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 199 days.
- Days to follow up: 295 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 371.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 168 cm; BMI: 24.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N8-A56S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,670 mg.
  Slide TCGA-N8-A56S-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-N8-A56S-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N8-A56S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Uterus; Anatomic organ subdivision: Unknown - Uterus NOS; Histologic diagnosis: Uterine Carcinosarcoma/ MMMT: Heterologous Type; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 371 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 371 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 199 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N8-A56S-01A-11D-A28Q-01): tumor purity 0.75, ploidy 3.48, whole-genome doublings 1.
